Somatic mutation profile of tumor specimen TCGA-AZ-6606-01A (aliquot TCGA-AZ-6606-01A-11D-1835-10) from TCGA case TCGA-AZ-6606, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 81.3 years (29,704 days).
Specimen TCGA-AZ-6606-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d42b6e82-e436-4c5b-bee9-aea79c8eb22d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AZ-6606-11A (Solid Tissue Normal), aliquot TCGA-AZ-6606-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e43f27b6-a53e-4947-bb72-3236cecb2f0f

The open-access MAF lists 147 somatic variants for this specimen: 100 protein-altering or splice-affecting, 44 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 44, Nonsense Mutation 11, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 61/116 reads (53%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 89/114 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 22/30 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRB3 | c.3218C>T p.T1073M | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs376079687; called by muse, mutect2, varscan2
- AFAP1 | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs569262471, COSV100631320; called by muse, mutect2, varscan2
- ANAPC1 | c.5200A>G p.K1734E | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100594620; called by muse, varscan2
- APC | c.2737del p.H913Ifs*3 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as COSV57373868; called by mutect2, pindel, varscan2
- APLP1 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 23/39 reads (59%) | catalogued as COSV99697631; called by muse, mutect2, varscan2
- APOA5 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1017355725, COSV57063025; called by muse, mutect2, varscan2
- AQP4 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV67219745; called by mutect2, varscan2
- ARHGEF15 | c.1780A>G p.I594V | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.825); catalogued as COSV100730024; called by muse, mutect2, varscan2
- ARHGEF40 | c.4042G>C p.E1348Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.639); catalogued as COSV53879917, COSV53881953; called by muse, mutect2, varscan2
- ARMC6 | c.982G>A p.D328N (on ENST00000392336; = p.D303N on NM_033415.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs761010517, COSV54182466; called by muse, mutect2, varscan2
- ARVCF | c.1726C>T p.R576W | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747415960, COSV54268154; called by muse, mutect2, varscan2
- C1orf74 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs568157466, COSV50558067; called by muse, mutect2, varscan2
- CALB2 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.777); catalogued as COSV56938350, COSV56939615; called by muse, mutect2, varscan2
- CAPSL | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs199837654; called by muse, mutect2, varscan2
- CD34 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 24/266 reads (9%) | catalogued as rs1558121188, COSV100178302; called by muse, mutect2
- CFH | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 59/281 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100809232; called by muse, mutect2, varscan2
- CHPF | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs750764885, COSV60535947; called by mutect2, varscan2
- COL5A1 | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100879746; called by muse, mutect2, varscan2
- COX6A2 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV54931841; called by muse, varscan2
- CPZ | c.967C>T p.R323* (on ENST00000360986 / NM_001014447.3; = p.R312* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100248893; called by muse, mutect2, varscan2
- CYP4A22 | c.1483G>A p.V495M | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53739835; called by muse, mutect2, varscan2
- DAB1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV59726872, COSV59730352; called by muse, mutect2, varscan2
- DISP3 | c.3865G>A p.V1289M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs545099796, COSV53838508; called by muse, mutect2, varscan2
- DNAH11 | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs763926220, COSV100178444; called by muse, mutect2, varscan2
- DTWD2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV58366020; called by muse, mutect2, varscan2
- DYNC1I2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1433633841, COSV99783759; called by muse, mutect2, varscan2
- EHBP1L1 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs761270987, COSV100499787; called by muse, mutect2, varscan2
- ENOX2 | c.554G>A p.R185H (on ENST00000338144 / NM_001382520.1; = p.R156H on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs770968891, COSV100583994, COSV57656785; called by muse, mutect2, varscan2
- EPS8L2 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV59347727; called by muse, mutect2, varscan2
- ERLEC1 | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs146951835; called by muse, mutect2, varscan2
- FAM153B | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 64/777 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99498853; called by muse, mutect2
- FAM71B | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261986; called by muse, mutect2, varscan2
- FCGBP | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 120/547 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs782167689; called by muse, mutect2, varscan2
- FGD2 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as COSV99236033; called by muse, mutect2, varscan2
- GALNT13 | c.1465G>T p.G489* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV101222484; called by muse, mutect2, varscan2
- GANC | c.1188G>A p.W396* | Nonsense Mutation (SNP) | VAF 48/129 reads (37%) | catalogued as rs1470176800, COSV100530811; called by muse, mutect2, varscan2
- GHR | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373412197; called by muse, mutect2, varscan2
- HDGFL2 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs1374620503, COSV100012180; called by muse, mutect2, varscan2
- HECTD2 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV53219682, COSV99978392; called by muse, mutect2, varscan2
- HIF3A | c.1055C>A p.S352Y (on ENST00000377670 / NM_152795.4; = p.S283Y on NM_022462.4) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99355673; called by muse, mutect2
- INHBA | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as rs779220866, COSV54226525; called by muse, mutect2, varscan2
- ITGAX | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs748801860, COSV99191578; called by muse, mutect2, varscan2
- KRTAP6-1 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | PolyPhen probably damaging (0.998); catalogued as COSV100228747; called by muse, mutect2, varscan2
- LETM2 | c.271C>A p.P91T (on ENST00000379957 / NM_001286819.2; = p.P44T on NM_144652.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99907341; called by muse, mutect2
- LINGO2 | c.118T>C p.S40P | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100430423; called by muse, mutect2, varscan2
- LUZP2 | c.771A>C p.Q257H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV61198015; called by mutect2, varscan2
- MAGEE1 | c.1205G>T p.S402I | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63909974; called by muse, mutect2, varscan2
- MELK | c.1943G>C p.S648T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.144); catalogued as COSV99974452; called by muse, mutect2, varscan2
- MYH3 | c.5461C>T p.R1821* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV56870812; called by muse, mutect2, varscan2
- MYO9B | c.2903G>A p.R968Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101261459; called by muse, mutect2, varscan2
- NEB | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs181244403, COSV51175797; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELL1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV100120360; called by muse, mutect2, varscan2
- NINL | c.3566G>T p.R1189L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs757265210, COSV99625053; called by muse, mutect2, varscan2
- NLGN1 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201897162, COSV64344687; called by muse, mutect2, varscan2
- NOS1 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs375069851; called by muse, mutect2, varscan2
- NOS1 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs755159260, COSV100500342; called by mutect2, varscan2
- NRAP | c.3208G>A p.E1070K (on ENST00000359988 / NM_001322945.2; = p.E1035K on NM_006175.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV100748368; called by muse, mutect2, varscan2
- NRXN2 | c.2632T>C p.F878L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99633432; called by mutect2, varscan2
- OR13H1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 71/89 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as rs766468103, COSV58547498; called by muse, mutect2, varscan2
- PCDH10 | c.2601C>G p.I867M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.31); catalogued as COSV99993302; called by muse, mutect2, varscan2
- PCDHB2 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs1320022364, COSV52031612; called by muse, mutect2, varscan2
- PIPOX | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100037917; called by muse, mutect2, varscan2
- PLOD1 | c.1902+1G>A p.X634_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV52143644; called by muse, mutect2, varscan2
- PPARGC1A | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.989); catalogued as COSV99337669; called by muse, mutect2, varscan2
- PTPRH | c.3316G>A p.A1106T | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs150929721; called by muse, mutect2, varscan2
- REXO5 | c.739A>T p.I247F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99759068; called by muse, mutect2, varscan2
- RIF1 | c.6523G>A p.A2175T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99690356; called by muse, mutect2
- RIMS1 | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs756787710, COSV99325597; called by muse, mutect2, varscan2
- SAA2-SAA4 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146072546, COSV53448048; called by muse, mutect2, varscan2
- SEMA4C | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs541764126, COSV100560845; called by muse, mutect2, varscan2
- SLC32A1 | c.1312G>A p.A438T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs1256431418, COSV99462031; called by muse, mutect2, varscan2
- SLC45A1 | c.1390G>A p.G464R | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs764318169, COSV57099232; called by muse, mutect2, varscan2
- SLC5A1 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs775315224, COSV56682874, COSV56684233; called by muse, mutect2, varscan2
- SPRR3 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as rs746832933, COSV99768489; called by muse, mutect2, varscan2
- STOX2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1192479663, COSV100408204, COSV57851546; called by muse, mutect2, varscan2
- TAF1L | c.4126C>T p.R1376* | Nonsense Mutation (SNP) | VAF 53/156 reads (34%) | catalogued as rs781629508, COSV99644412; called by muse, mutect2, varscan2
- TBC1D9B | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1196788168, COSV100783478; called by muse, mutect2, varscan2
- TG | c.6160G>C p.E2054Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV99600014; called by muse, mutect2, varscan2
- TLL1 | c.2243C>T p.T748M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs746510010, COSV50331635; called by muse, mutect2, varscan2
- TSHZ2 | c.710C>T p.T237M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs768300914, COSV100295772; called by muse, mutect2, varscan2
- TTLL9 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.081); catalogued as rs773056812, COSV100206553; called by muse, mutect2, varscan2
- UGGT1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99390514; called by muse, mutect2, varscan2
- USH2A | c.11872A>C p.T3958P | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1461879422, COSV56337423; called by muse, mutect2
- USP24 | c.5618G>C p.C1873S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV99599296; called by muse, mutect2, varscan2
- USP34 | c.4358G>C p.R1453T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101276876; called by muse, mutect2, varscan2
- USP7 | c.2974G>A p.V992M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100784120; called by muse, mutect2, varscan2
- WNK4 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779595489, COSV55903235, COSV55908545; called by muse, mutect2, varscan2
- ZNF175 | c.1076G>T p.R359I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs775192879, COSV99219372; called by muse, mutect2, varscan2
- ZNF175 | c.1301T>C p.L434P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99219376; called by muse, mutect2, varscan2
- ZNF200 | c.1076A>G p.E359G | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV101205221; called by muse, mutect2, varscan2
- CHD1 | c.2838_2839del p.V947Tfs*15 | Frame Shift Del (DEL) | VAF 21/109 reads (19%) | called by mutect2, pindel, varscan2
- COBL | c.2948del p.Q983Rfs*82 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | called by mutect2, pindel, varscan2
- GABRG3 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- IGHV1OR21-1 | c.284T>G p.M95R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INHBA | c.1141_1144delinsAT p.H381Mfs*24 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by pindel, varscan2*
- MELTF | c.191_195dup p.L66Sfs*28 | Frame Shift Ins (INS) | VAF 34/87 reads (39%) | called by mutect2, pindel, varscan2
- VASN | c.343dup p.I115Nfs*4 | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- ACTL9 | c.621C>T p.P207= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as COSV61005082; called by muse, mutect2, varscan2
- ARHGAP35 | c.4167T>C p.N1389= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV101350886; called by muse, mutect2, varscan2
- BSX | c.594C>T p.A198= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100545178, COSV58006588; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.849G>A p.A283= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs138943358; called by muse, mutect2, varscan2
- CYLD | c.648C>T p.Y216= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs772493242, COSV100282329; called by mutect2, varscan2
- DIP2C | c.3660C>G p.A1220= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV55145025, COSV55179007; called by muse, mutect2, varscan2
- ENAM | c.2172G>A p.P724= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs149573021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGF21 | c.147C>T p.L49= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV55810272; called by muse, mutect2, varscan2
- GLI2 | c.3141C>T p.D1047= (on ENST00000361492 / NM_001374353.1; = p.D1064= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs756394134, COSV58036503; called by muse, mutect2, varscan2
- GRIA3 | c.1629C>A p.G543= | Silent (SNP) | VAF 72/100 reads (72%) | catalogued as rs780335659, COSV52059000, COSV99989584; called by muse, mutect2, varscan2
- H2BC10 | c.177T>A p.A59= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV59952947, COSV59953663; called by muse, mutect2, varscan2
- LRCH1 | c.513C>T p.I171= | Silent (SNP) | VAF 32/229 reads (14%) | catalogued as rs770538140, COSV60846827; called by muse, mutect2, varscan2
- MAGEC1 | c.2253T>C p.T751= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99595343; called by muse, mutect2, varscan2
- MEGF8 | c.2085C>T p.S695= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV52082786; called by muse, mutect2, varscan2
- MPPED1 | c.396C>T p.N132= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as rs368415701; called by muse, mutect2, varscan2
- MTMR4 | c.1995G>A p.G665= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100050929; called by muse, mutect2, varscan2
- NOD2 | c.135G>A p.L45= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV100318399; called by muse, mutect2, varscan2
- NPEPL1 | c.1419G>A p.E473= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100622388; called by muse, mutect2
- NRIP1 | c.3147G>A p.A1049= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs750298287, COSV59656202; called by muse, mutect2, varscan2
- OR10X1 | c.744G>A p.E248= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as rs767058852, COSV100936623; called by muse, mutect2, varscan2
- OR5R1 | c.559C>T p.L187= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100393349, COSV100393573, COSV56572646; called by muse, mutect2, varscan2
- PAAF1 | c.339C>T p.D113= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs369147574; called by muse, mutect2, varscan2
- PBXIP1 | c.447C>T p.D149= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as rs776039240, COSV100870050; called by muse, mutect2, varscan2
- PCDH9 | c.927T>A p.T309= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100119539; called by muse, mutect2
- PCDHB7 | c.1488G>A p.P496= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs782696366, COSV99176618; called by muse, mutect2, varscan2
- PCDHGB4 | c.2205C>T p.S735= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV53936832; called by muse, mutect2, varscan2
- PDZD2 | c.6501G>A p.L2167= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99224486; called by muse, mutect2, varscan2
- PKDREJ | c.4593G>T p.P1531= | Silent (SNP) | VAF 81/206 reads (39%) | catalogued as COSV99478649; called by muse, mutect2, varscan2
- PLCG1 | c.3168G>A p.T1056= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs766145575, COSV99718696; called by muse, mutect2, varscan2
- PRAMEF2 | c.1191G>T p.L397= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV53574894; called by muse, varscan2
- PRNP | c.423C>T p.F141= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs764920854, COSV65173547; called by muse, mutect2, varscan2
- RAB5C | c.18C>T p.G6= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1474140273, COSV60525612; called by muse, mutect2, varscan2
- RASA3 | c.1524G>A p.T508= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as rs202142638, COSV61869931; called by muse, mutect2
- RBL1 | c.2407T>C p.L803= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV60335181; called by muse, mutect2
- ROR2 | c.2349C>T p.N783= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs761291207, COSV100995391; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC25A23 | c.504C>T p.C168= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99902099; called by muse, varscan2
- SPAG11B | c.231G>A p.R77= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as COSV52499522; called by muse, mutect2, varscan2
- TBCA | c.156G>A p.K52= | Silent (SNP) | VAF 237/504 reads (47%) | catalogued as COSV100115909; called by muse, mutect2, varscan2
- TMEM64 | c.1131C>T p.I377= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as COSV101376024; called by muse, mutect2, varscan2
- TNPO1 | c.90C>T p.S30= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- VPS13B | c.427C>T p.L143= | Silent (SNP) | VAF 10/141 reads (7%) | catalogued as COSV62018894; called by muse, mutect2
- VSTM1 | c.6C>T p.T2= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs762908715, COSV58074916; called by muse, mutect2, varscan2
- ZC3H13 | c.4437G>A p.K1479= (on ENST00000242848 / NM_001330565.2; = p.K1480= on NM_015070.6) | Silent (SNP) | VAF 24/452 reads (5%) | catalogued as rs758551038, COSV99667852; called by muse, mutect2
- ZNF813 | c.666A>G p.K222= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV101124753; called by muse, mutect2
- ELAVL4 | chr1:50106376 A>C | 5'Flank (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100836570, COSV100836662; called by muse, mutect2
- NCAM1 | c.1826-3540G>T | Intron (SNP) | VAF 8/35 reads (23%) | catalogued as COSV57515423; called by muse, mutect2, varscan2
- ZNF665 | c.-53-9136A>G | Intron (SNP) | VAF 5/49 reads (10%) | catalogued as COSV101128178; called by muse, mutect2, varscan2
